Gene-level copy-number profile of tumor specimen TCGA-06-0171-02A from TCGA case TCGA-06-0171, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.9 years (24,085 days).
Specimen TCGA-06-0171-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.6c437c25-69bc-42ca-a070-bafdd5b27089.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0171-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 392 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b6e60d8-9a99-4ebc-90b0-da87ec15a3c6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,555; copy number 1: 6,319; copy number 2: 46,112; copy number 3: 5,050; copy number 4: 8; copy number 5: 43; copy number 6: 32; copy number 7: 6; copy number 9: 106.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0171-02A-11D-2002-01): tumor purity 0.22, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 174 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,384,059–75,590,649, 11 genes: AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1.
- chr6:30,516,266–30,557,174, 2 genes: LINC02569, GNL1.
- chr10:48,510,525–48,546,713, 2 genes: ARHGAP22-IT1, AC016397.1.
- chr15:19,878,555–22,282,872, 128 genes (broad region; genes not listed).
- chr15:30,282,533–30,772,993, 30 genes (within-gene range 0–2): AC135731.2, AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8, GOLGA8H, AC026150.3, RN7SL628P, AC091057.3, AC091057.2, ARHGAP11B, AC091057.5, AC091057.6, AC091057.1, Y_RNA.
- chr17:41,314,912–41,315,710, 1 gene: KRTAP17-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 187 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:73,104,792–73,106,282, 1 gene, copy number 5: KRT8P21.
- chr2:86,861,825–88,128,062, 40 genes, copy number 5 (within-gene range 2–5): ANAPC1P1, AC111200.1, RGPD1, WBP1P1, NDUFB4P5, PLGLB1, ANAPC1P2, ANAPC1P2, AC092651.1, AC092651.2, ANAPC1P3, AC083899.1, MIR4771-1, CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943, CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5, ANAPC1P4, PLGLB2, RGPD2, MTATP8P2, NDUFB4P7, WBP1P2, ANAPC1P5, AC108479.2, RNU2-63P, AC108479.1, KRCC1, SMYD1, MIR4780, FABP1.
- chr8:2,493,876–2,728,577, 6 genes, copy number 7: AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2.
- chr14:36,070,427–36,176,468, 2 genes, copy number 5 (within-gene range 2–5): LINC00609, PTCSC3.
- chr14:105,764,503–106,377,733, 106 genes, copy number 9 (broad region; genes not listed).
- chr15:31,765,743–32,186,475, 6 genes, copy number 6: DEPDC1P1, AC026951.1, CHRNA7, AC079969.1, Y_RNA, AC068448.1.
- chr16:35,207,884–35,284,146, 1 gene, copy number 6 (within-gene range 2–6): AC023824.3.
- chr16:35,232,412–35,496,457, 24 genes, copy number 6: FGFR3P5, FRG2JP, RARRES2P6, AGGF1P8, FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3.
- chr16:35,504,370–35,506,567, 1 gene, copy number 6: AC018558.1.

Autosomal genes at a single copy (total copy number 1): 5,770. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
